TARGET case TARGET-30-PALNVP — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Other and ill-defined sites. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/328808f2-2db0-5b37-8c43-9878b29c4f0f

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 3 years; Vital status: Alive.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C76.3; Tissue or organ of origin: Pelvis, NOS; Classification of tumor: primary; Age at diagnosis: 3.2 years (1,155 days); Year of diagnosis: 2002; Days to last follow up: 4,936 days (13.5 years); Cog neuroblastoma risk group: High Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 4; Mitosis karyorrhexis index: Low.
   Pathology details: Necrosis percent: 5; Percent tumor nuclei: 90.
   Treatment given: Protocol identifier: A3973.
   Treatment given: Protocol identifier: ANBL00B1.

Follow-up (1 entry)
- Days to follow up: 4,936 days (13.5 years); Event-free: no event (relapse, second malignancy or death) recorded through day 4,936; Year of follow up: 2015.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Abnormal, NOS; Ploidy: Hyperdiploid.

Biospecimens (2 samples)
- Sample TARGET-30-PALNVP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PALNVP-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- First Event: Censored
- Overall Survival Time in Days: 4936
- Protocol: ANBL00B1, A3973
- Ploidy: Hyperdiploid (DI>1)
- Ploidy Value: 1.44
- Histology: Unfavorable
- MKI: Low
- ICDO Description: Pelvis, NOS Buttock, NOS Groin, NOS Ischiorectal fossa Pelvic wall, NOS Perineum, NOS Rectovaginal septum Rectovesical septum Gluteal region, NOS Inguinal region, NOS Perirectal region, NOS Presacral region, NOS Sacrococcygeal region, NOS
- Percent Necrosis: 5
